Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7422, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7422-01A (Primary Tumor).

[page 1 of 2]
SUPPLEMENTAL REPORT

COMMENT: Decalcified sections of thyroid cartilage and hyoid bone have been examined. The tumor does not invade into thyroid cartilage or bone.

SECTION CODE: C42-C46, representative sections of right side; C47, midline, C48-49, hyoid bone.

DIAGNOSIS

(A) LEFT PARATRACHEAL TISSUE:

Thymus, no evidence of malignancy.

(B) RIGHT PARATRACHEAL TISSUE:

METASTATIC SQUAMOUS CARCINOMA 1 OF 2 LYMPH NODES.

(C) TOTAL LARYNGECTOMY, AND BILATERAL NECK DISSECTION:

INVASIVE POORLY DIFFERENTIATED SQUAMOUS CARCINOMA WITH TRANSGLOTTIC INVOLVEMENT OF RIGHT SIDE OF LARYNX, AND EXTENSION INTO ANTERIOR COMMISSURE, RIGHT ARYEPIGLOTTIC FOLD, PRE-EPIGLOTTIC SPACE AND SOFT TISSUE OF ANTERIOR NECK. (SEE COMMENT)

EXTENSIVE LYMPHOVASCULAR INVASION INVOLVING RIGHT AND LEFT SIDE OF LARYNX AND SOFT TISSUE PRESENT.

INVASIVE CARCINOMA EXTENDS TO RIGHT LATERAL AND ANTERIOR MARGINS. (SEE COMMENT)

Tracheal, left mucosal and anterior and posterior soft tissue margins free of tumor.

Severe squamous dysplasia involving left side of larynx.

Tracheostomy site, marked acute and chronic inflammation and foreign body giant cell reaction.

Thyroid gland with focal areas of fibrosis and inflammation.

Two right parathyroid glands.

METASTATIC SQUAMOUS CARCINOMA IN ONE OF FIVE RIGHT SUBDIGASTRIC LYMPH NODES WITH EXTRANODAL TUMOR EXTENSION.

Five right midjugular lymph nodes, no tumor present.

Seventeen left neck lymph nodes, no tumor present (6 subdigastric, 5 midjugular, and 6 lower jugular).

Thymic tissue.

(D) RIGHT PYRIFORM SINUS:

Squamous mucosa and skeletal muscle, no tumor present.

(E) LEFT PYRIFORM SINUS:

Squamous mucosa and skeletal muscle, no tumor present.

[page 2 of 2]
- [REDACTED]
- (F) BASE OF TONGUE:
Squamous mucosa with lymphoid tissue and minor salivary gland,
no tumor present.
- (G) PARATHYROID:
Parathyroid tissue, no tumor present.

COMMENT

The tumor forms an ulcerated mass (2.5 x 2.5 x 1.0 cm) involving right supraglottis, glottis and subglottis. It crosses midline and involves anterior commissure, right aryepiglottic fold and pre-epiglottic space. Although the tumor extends to the right mucosal margins of this specimen anteriorly and laterally, true margins submitted separately from these areas (Specimens D and F) are free of tumor. Lymphovascular invasion is identified in multiple sections. The largest lymph node metastasis measures 1.0 cm.

[REDACTED]

SPECIMEN

- (A) LEFT PARATRACHEAL TISSUE:
(B) RIGHT PARATRACHEAL TISSUE:
(C) TOTAL LARYNGECTOMY, AND BILATERAL NECK DISSECTION:
(D) RIGHT PYRIFORM SINUS:
(E) LEFT PYRIFORM SINUS:
(F) BASE OF TONGUE:
(G) PARATHYROID:

SNOMED CODES

T-24100, M-80703, T-C4200, M-80706

Source: NCI Genomic Data Commons file d91ba9cb-15c9-4e84-b2d1-128cb6a8bcdf (TCGA-CV-7422.8B27DDBA-4DCA-45A7-905C-D68630D8EA99.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).